Gene-level copy-number profile of tumor specimen SM-JU33G from CPTAC case C464694, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU33G: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1a6f2253-f02c-4f6a-9055-3c9df282f908.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105273 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/c79786cc-1765-4fde-ada6-55d4f33eefc5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 267; copy number 2: 9,710; copy number 3: 14,099; copy number 4: 31,372; copy number 5: 2,448; copy number 6: 333; copy number 7: 17; copy number 8: 5; copy number 11: 10; copy number 13: 16; copy number 15: 1; copy number 16: 11; copy number 18: 2; copy number 22: 6; copy number 24: 12; copy number 26: 2; copy number 42: 5; copy number 43: 1; copy number 44: 13; copy number 45: 11; copy number 79: 31.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,233,288–4,288,083, 4 genes: SSU72P5, SSU72P2, SSU72P6, SSU72P4.
- chr11:55,602,360–55,640,309, 2 genes: OR4C11, OR4P4.
- chr17:18,450,244–18,494,945, 5 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 82 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:31,073,860–31,369,301, 13 genes, copy number 44: DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6.
- chr12:57,674,665–58,105,935, 31 genes, copy number 79: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:64,759,484–65,248,355, 13 genes, copy number 26–45: TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:69,584,722–69,699,476, 6 genes, copy number 22: MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:75,234,740–75,511,636, 10 genes, copy number 24: CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1.
- chr12:76,344,474–76,348,415, 1 gene, copy number 15: BBS10.
- chr12:93,266,017–93,266,096, 1 gene, copy number 43: AC126172.1.
- chr12:98,113,014–98,318,349, 2 genes, copy number 24: AC016152.1, AC008055.1.
- chr12:102,012,840–102,062,149, 1 gene, copy number 45: WASHC3.
- chr12:107,271,394–107,659,642, 4 genes, copy number 45 (within-gene range 4–45): SETP7, BTBD11, AC009774.1, RNA5SP371.

Autosomal genes at a single copy (total copy number 1): 267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
